Surgical pathology report (de-identified scan), TCGA case TCGA-85-7950, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-7950-01A (Primary Tumor).

[page 1 of 4]
Case ID	OpenClinica ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details

Comments

[page 3 of 4]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Pneumonectomy

Tumor site: Lung

Tumor size: 2.5 x 2.5 x 4 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Laterality

Left-upper

[page 4 of 4]
Excision date

[REDACTED]

Source: NCI Genomic Data Commons file 75b298aa-43d1-460a-b605-d1cb11659c6f (TCGA-85-7950.1664B418-9F16-426A-B9DD-279995F3F8C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).